Somatic mutation profile of tumor specimen HTMCP-03-06-02385-01A (aliquot HTMCP-03-06-02385-01A-01D-10409) from CGCI case HTMCP-03-06-02385, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G3.
Specimen HTMCP-03-06-02385-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad5ae6f0-9f64-41b9-9b55-45749923630b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02385-10A (Blood Derived Normal), aliquot HTMCP-03-06-02385-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a96f2874-c6c0-4e4d-b4ad-e4fd9ac4cfb3

The open-access MAF lists 189 somatic variants for this specimen: 129 protein-altering or splice-affecting, 49 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 49, Nonsense Mutation 21, Intron 7, Splice Site 3, RNA 2, In Frame Del 1, 5'UTR 1, 3'UTR 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 35/132 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRG4 | c.1646C>G p.S549W | Missense Mutation (SNP) | VAF 115/484 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV54959465; called by muse, mutect2, varscan2
- AGBL5 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1269161861; called by muse, mutect2, varscan2
- AMBRA1 | c.2977-1G>C p.X993_splice (on ENST00000458649 / NM_001367468.1; = p.X903_splice on NM_017749.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 32/84 reads (38%) | catalogued as COSV54048471; called by muse, mutect2, varscan2
- ANKRD30B | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.607); catalogued as rs571321972, COSV57702787; called by muse, varscan2
- ARID1A | c.2489G>C p.G830A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV61382258; called by muse, mutect2, varscan2
- ATP2B3 | c.2986G>A p.V996M | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs782715889, COSV54850450; called by muse, mutect2, varscan2
- AURKA | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866281286; called by muse, mutect2, varscan2
- BCHE | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as rs1418971053; called by muse, mutect2, varscan2
- BCLAF1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 61/330 reads (18%) | catalogued as COSV62144100; called by muse, mutect2, varscan2
- BRD1 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs368291617; called by muse, varscan2
- C6orf118 | c.1124C>A p.S375* | Nonsense Mutation (SNP) | VAF 33/151 reads (22%) | catalogued as COSV57816768; called by muse, mutect2, varscan2
- CEP290 | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs751441268; called by muse, mutect2, varscan2
- CFAP43 | c.2866G>C p.E956Q | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.943); catalogued as COSV99530741; called by muse, mutect2, varscan2
- CTBP1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1407102746, COSV99337963; called by muse, mutect2, varscan2
- DACT1 | c.1154C>A p.S385* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV60019433; called by muse, mutect2, varscan2
- DHX16 | c.2990T>C p.M997T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756363044; called by muse, mutect2, varscan2
- DNAH5 | c.10877C>T p.T3626M | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376067762, COSV54221968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK11 | c.4519C>G p.L1507V | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV52234619; called by muse, mutect2, varscan2
- DOCK4 | c.2850G>C p.Q950H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs774619177; called by muse, mutect2, varscan2
- DUSP10 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1256262280, COSV60458322; called by muse, mutect2, varscan2
- EPHA5 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV56649453; called by muse, mutect2, varscan2
- ERAP1 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748941555; called by muse, mutect2, varscan2
- EVC2 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.401); catalogued as rs369748879; called by muse, mutect2, varscan2
- F9 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 165/627 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as CM940652, CM960599, COSV54382355; called by muse, mutect2, varscan2
- FAAP100 | c.1764G>C p.E588D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs371562845; called by muse, mutect2, varscan2
- GALNTL6 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV72489194; called by muse, mutect2, varscan2
- GON4L | c.3727C>T p.Q1243* | Nonsense Mutation (SNP) | VAF 68/188 reads (36%) | catalogued as COSV55187758; called by muse, mutect2, varscan2
- GRIN2A | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs1567354612, COSV58029591; called by muse, mutect2, varscan2
- HEATR1 | c.6242G>A p.R2081Q | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs761992655; called by muse, mutect2, varscan2
- KCNA5 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375520270, COSV52904004; called by muse, mutect2, varscan2
- MAP3K10 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455727337, COSV53422885; called by muse, mutect2, varscan2
- MGA | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54958918, COSV54960833; called by muse, mutect2, varscan2
- MYH7 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs727504416, COSV100806536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH4 | c.5506G>C p.E1836Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as COSV66679424, COSV66679988, COSV66681239; called by muse, mutect2
- NUP133 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV54574655; called by muse, mutect2, varscan2
- NUP153 | c.3478G>C p.E1160Q | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV50458313; called by muse, mutect2, varscan2
- OTC | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs148660170; called by muse, mutect2, varscan2
- PADI2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs773702493; called by muse, mutect2, varscan2
- PCDHB8 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 233/363 reads (64%) | catalogued as COSV50761908; called by muse, mutect2, varscan2
- PCDHGB1 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 85/111 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1460025344; called by muse, mutect2, varscan2
- PLEC | c.4426G>A p.E1476K (on ENST00000322810 / NM_201380.4; = p.E1366K on NM_000445.5) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs781823105, COSV100515744, COSV59642285; called by muse, mutect2, varscan2
- PNISR | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV65080019; called by muse, mutect2, varscan2
- PTCH1 | c.4240G>A p.V1414M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs149667902; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- PTCH1 | c.2315G>A p.R772K | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV59469246; called by muse, mutect2, varscan2
- REV3L | c.2782G>T p.E928* | Nonsense Mutation (SNP) | VAF 58/230 reads (25%) | catalogued as COSV62622102; called by muse, mutect2, varscan2
- RLIM | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1304657960, COSV60327800; called by muse, mutect2, varscan2
- SMC4 | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 53/184 reads (29%) | catalogued as rs960920466, COSV61006337; called by muse, mutect2, varscan2
- SPEN | c.4253G>A p.R1418Q | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs938826668; called by muse, mutect2, varscan2
- SSH2 | c.4225G>A p.A1409T | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.003); catalogued as rs762543945; called by muse, mutect2, varscan2
- SYNE1 | c.16228C>T p.R5410* (on ENST00000367255 / NM_182961.4; = p.R5339* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 48/89 reads (54%) | catalogued as COSV99573999; called by muse, mutect2, varscan2
- TIMELESS | c.2881G>C p.E961Q | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV99973735; called by muse, mutect2, varscan2
- TOPORS | c.3068C>T p.S1023L | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs751258105; called by muse, mutect2, varscan2
- TSHZ2 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs772820249, COSV61588900; called by muse, mutect2, varscan2
- TTN | c.59015G>T p.W19672L (on ENST00000591111; = p.W12248L on NM_003319.4) | Missense Mutation (SNP) | VAF 119/212 reads (56%) | PolyPhen probably damaging (0.997); catalogued as COSV60069978; called by muse, mutect2, varscan2
- UNC5B | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747312686, COSV58977174; called by muse, mutect2, varscan2
- UNC80 | c.2471G>A p.R824Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.947); catalogued as rs1468887382; called by muse, mutect2, varscan2
- USP34 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV101277197, COSV68402748; called by muse, mutect2, varscan2
- ZNF208 | c.1786C>A p.L596I | Missense Mutation (SNP) | VAF 41/456 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs945753533; called by muse, mutect2
- ZNF469 | c.8988G>C p.E2996D (on ENST00000437464; = p.E3024D on NM_001367624.2) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1224147225; called by muse, mutect2, varscan2
- ZNF546 | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1032531954; called by muse, mutect2
- ZNF568 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 50/244 reads (20%) | catalogued as rs770596753, COSV101426806; called by muse, mutect2
- ZNF708 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 47/441 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs1244249438; called by muse, mutect2, varscan2
- ABCA8 | c.3058C>A p.L1020I | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ARHGAP4 | c.1590C>A p.F530L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ARHGAP6 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ASH1L | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP13A4 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATR | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ATXN3L | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 25/371 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); called by muse, mutect2
- BABAM2 | c.689G>C p.G230A | Missense Mutation (SNP) | VAF 105/209 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRWD3 | c.4188A>T p.Q1396H | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- C2CD3 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- CCDC88A | c.5262G>C p.L1754F (on ENST00000436346 / NM_001365480.1; = p.L1726F on NM_018084.5) | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CDH11 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CFTR | c.3139+2_3139+19del p.X1047_splice | Splice Site (DEL) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- CLASP2 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- CLSPN | c.803C>G p.S268* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- CNOT6L | c.1228G>C p.D410H (on ENST00000504123 / NM_001286790.2; = p.D405H on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL1A2 | c.936+1G>A p.X312_splice | Splice Site (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- CUL4B | c.1706C>G p.S569* | Nonsense Mutation (SNP) | VAF 35/258 reads (14%) | called by muse, mutect2, varscan2
- DACT1 | c.1454C>A p.S485Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, varscan2
- DACT1 | c.1529C>G p.S510* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | called by muse, varscan2
- DACT1 | c.2401C>G p.L801V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DDB1 | c.3113-3C>A | Splice Region (SNP) | VAF 52/168 reads (31%) | called by muse, mutect2, varscan2
- DDX3X | c.998G>A p.G333E (on ENST00000399959; = p.G334E on NM_001356.5) | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DZIP1L | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EP400 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS8 | c.2388dup p.M797Yfs*13 | Frame Shift Ins (INS) | VAF 48/134 reads (36%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.2165C>A p.S722* | Nonsense Mutation (SNP) | VAF 49/127 reads (39%) | called by muse, mutect2, varscan2
- GPATCH8 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GPATCH8 | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPR179 | c.2746C>T p.H916Y (on ENST00000621958; = p.H915Y on NM_001004334.4) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2
- GRIPAP1 | c.1553T>G p.M518R | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- HUWE1 | c.4693C>T p.Q1565* | Nonsense Mutation (SNP) | VAF 67/303 reads (22%) | called by muse, mutect2, varscan2
- ITSN1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KCNJ6 | c.987G>C p.E329D | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF1B | c.3660_3686del p.F1220_P1229delinsL (on ENST00000377086 / NM_001365952.1; = p.F1174_P1183delinsL on NM_015074.3) | In Frame Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel
- KIF5C | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- LILRB4 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- LTBP3 | c.262T>A p.S88T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC3 | c.1238A>T p.Q413L | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- MUC4 | c.4727C>G p.S1576* | Nonsense Mutation (SNP) | VAF 62/264 reads (23%) | called by muse, varscan2
- MYH10 | c.3898G>A p.E1300K | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PCLO | c.5236A>G p.S1746G | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3C2B | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- PKDREJ | c.2962C>T p.Q988* | Nonsense Mutation (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- PKHD1 | c.3386G>C p.G1129A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PPIP5K2 | c.3329C>G p.S1110* | Nonsense Mutation (SNP) | VAF 60/173 reads (35%) | called by muse, mutect2, varscan2
- PSIP1 | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RBM39 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SHKBP1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, varscan2
- SHROOM4 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SLC9C1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMG6 | c.1017G>C p.Q339H | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SYNE1 | c.16588G>C p.E5530Q (on ENST00000367255 / NM_182961.4; = p.E5459Q on NM_033071.3) | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TBRG1 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TENM1 | c.4544A>G p.N1515S | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TMC4 | c.450G>T p.K150N (on ENST00000617472 / NM_001145303.3; = p.K144N on NM_144686.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- UBE2Q1 | c.755C>A p.A252D | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UNC80 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UTP20 | c.7975G>A p.G2659R | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VPS8 | c.3853C>A p.H1285N (on ENST00000625842 / NM_001349294.1; = p.H1283N on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR87 | c.4189C>T p.Q1397* | Nonsense Mutation (SNP) | VAF 60/618 reads (10%) | called by muse, mutect2
- YLPM1 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ZBTB21 | c.2638G>C p.E880Q | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZC3H6 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF208 | c.3226A>T p.K1076* | Nonsense Mutation (SNP) | VAF 48/436 reads (11%) | called by muse, mutect2, varscan2
- ZP2 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ACAN | c.4599A>G p.E1533= | Silent (SNP) | VAF 103/272 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.99C>T p.D33= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as rs782706817; called by muse, mutect2, varscan2
- ATP13A4 | c.2943C>T p.L981= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs771709125; called by muse, mutect2, varscan2
- ATP13A5 | c.1446C>T p.L482= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as rs1309813514, COSV60868536; called by muse, mutect2, varscan2
- BCL11B | c.1410C>G p.L470= (on ENST00000357195 / NM_001282237.2; = p.L399= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100595709; called by muse, mutect2, varscan2
- BNC2 | c.3231A>G p.V1077= | Silent (SNP) | VAF 38/117 reads (32%) | called by muse, mutect2, varscan2
- BRINP1 | c.375C>T p.Y125= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs115548564, COSV56299739, COSV56309285; called by muse, mutect2, varscan2
- BRS3 | c.705C>G p.V235= | Silent (SNP) | VAF 135/709 reads (19%) | called by muse, mutect2, varscan2
- CACNA1F | c.459C>T p.L153= | Silent (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- CDH8 | c.2361C>T p.G787= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as rs200638903, COSV54848805, COSV54878827; called by muse, mutect2, varscan2
- CFAP47 | c.258G>A p.L86= | Silent (SNP) | VAF 55/254 reads (22%) | called by muse, mutect2, varscan2
- CHD9 | c.2052G>C p.P684= | Silent (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- CNTN6 | c.504G>A p.E168= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs777498766, COSV63189178; called by muse, mutect2, varscan2
- COL19A1 | c.333C>T p.N111= | Silent (SNP) | VAF 71/125 reads (57%) | catalogued as rs143252227; called by muse, mutect2, varscan2
- COL6A5 | c.3390G>A p.L1130= | Silent (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- DCHS1 | c.8871C>T p.V2957= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1309607335; called by muse, mutect2, varscan2
- DISP3 | c.3882C>G p.V1294= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs762543476; called by muse, mutect2, varscan2
- DNAH17 | c.8961C>T p.I2987= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs780649583, COSV101101666; called by muse, mutect2, varscan2
- DNAH2 | c.9255G>A p.Q3085= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV66723029; called by muse, mutect2, varscan2
- DNAH7 | c.4968C>T p.Y1656= | Silent (SNP) | VAF 96/163 reads (59%) | catalogued as rs201006443, COSV56757174; called by muse, mutect2, varscan2
- DNAI2 | c.528G>A p.R176= | Silent (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- DROSHA | c.3606C>G p.T1202= | Silent (SNP) | VAF 52/103 reads (50%) | called by muse, mutect2, varscan2
- EEF2K | c.1242G>A p.V414= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1191699483; called by muse, mutect2, varscan2
- ERCC6 | c.3846G>A p.V1282= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1298075020; called by muse, mutect2, varscan2
- GEMIN5 | c.720C>T p.C240= | Silent (SNP) | VAF 43/139 reads (31%) | called by muse, mutect2, varscan2
- HLA-DQB2 | c.144G>C p.G48= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV101369901; called by muse, mutect2, varscan2
- INSR | c.2067C>T p.F689= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as rs776263155; called by muse, mutect2, varscan2
- INSR | c.1974C>T p.F658= | Silent (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- KMT2E | c.5433C>T p.F1811= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV57581046; called by muse, mutect2, varscan2
- LENG8 | c.2607C>A p.V869= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2
- LTN1 | c.4527G>A p.L1509= | Silent (SNP) | VAF 29/200 reads (15%) | called by muse, mutect2, varscan2
- MAGEB16 | c.974G>A p.*325= | Silent (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- MYOM2 | c.4365C>T p.L1455= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs202224359, COSV50701986; called by muse, mutect2, varscan2
- NEXMIF | c.1393C>A p.R465= | Silent (SNP) | VAF 14/338 reads (4%) | catalogued as COSV50021564; called by muse, mutect2
- OCA2 | c.231T>A p.S77= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- PCDHB14 | c.612G>A p.Q204= | Silent (SNP) | VAF 87/233 reads (37%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.963G>A p.T321= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs769621988, COSV63048352; called by muse, mutect2, varscan2
- SHROOM3 | c.5370C>T p.L1790= | Silent (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- SMG6 | c.678G>A p.V226= | Silent (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- SNRNP200 | c.4377C>T p.I1459= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as rs191438128; called by muse, mutect2, varscan2
- SPTA1 | c.6679C>T p.L2227= | Silent (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- STARD9 | c.4632C>G p.L1544= | Silent (SNP) | VAF 68/100 reads (68%) | called by muse, mutect2, varscan2
- STARD9 | c.6579C>T p.F2193= | Silent (SNP) | VAF 101/170 reads (59%) | called by muse, mutect2, varscan2
- TIAM2 | c.1128C>T p.L376= | Silent (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- TLL2 | c.2466G>A p.E822= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.42387G>A p.V14129= (on ENST00000591111; = p.V6705= on NM_003319.4) | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV59890310, COSV60005949; called by muse, mutect2, varscan2
- UTRN | c.48C>T p.N16= | Silent (SNP) | VAF 57/104 reads (55%) | catalogued as rs760717973; called by muse, mutect2, varscan2
- ZMAT1 | c.1338T>C p.C446= | Silent (SNP) | VAF 80/494 reads (16%) | catalogued as COSV65659545; called by muse, mutect2, varscan2
- ZNF14 | c.1893A>G p.R631= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs774993970; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2670G>C | Intron (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100153530; called by muse, mutect2, varscan2
- DOCK8 | c.53+191G>A | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs766584349; called by muse, varscan2
- EIF2AK1 | c.*796G>A | 3'UTR (SNP) | VAF 56/163 reads (34%) | called by muse, mutect2, varscan2
- FAM86GP | n.368C>T | RNA (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2, varscan2
- FARP2 | c.1411+617C>A | Intron (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- FARP2 | c.1411+945C>G | Intron (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- MATN2 | c.2815+86G>A | Intron (SNP) | VAF 29/79 reads (37%) | catalogued as rs1273073827; called by muse, mutect2, varscan2
- MUC19 | n.11382C>T | RNA (SNP) | VAF 230/777 reads (30%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2394+11C>G | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- SLC38A2 | c.705+9G>C | Intron (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- TPR | c.-16C>T | 5'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
